Somatic mutation profile of tumor specimen TCGA-BA-5558-01A (aliquot TCGA-BA-5558-01A-01D-1512-08) from TCGA case TCGA-BA-5558, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; Tumor grade: G1; Age at diagnosis: 65.7 years (23,984 days).
Specimen TCGA-BA-5558-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5a76bd9-9494-4646-be2f-d86a95ab3ae7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-5558-10A (Blood Derived Normal), aliquot TCGA-BA-5558-10A-01D-1512-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d5f7a38-1caa-469d-bcfb-0a4f7bcb0c92

The open-access MAF lists 167 somatic variants for this specimen: 112 protein-altering or splice-affecting, 52 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 52, Nonsense Mutation 9, Frame Shift Del 3, Splice Region 2, RNA 2, Frame Shift Ins 1, Intron 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 13/29 reads (45%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 26/105 reads (25%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACADSB | c.881G>C p.R294T | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100715342; called by muse, mutect2, varscan2
- ADAMTS19 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.46); catalogued as COSV99179010, COSV99183660; called by muse, mutect2, varscan2
- ADCY1 | c.3232G>T p.G1078W | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); catalogued as COSV52037894; called by muse, mutect2, varscan2
- ADGRF2 | c.1370C>G p.S457C (on ENST00000296862 / NM_001368115.2; = p.S389C on NM_153839.7) | Missense Mutation (SNP) | VAF 61/264 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99731966; called by muse, mutect2, varscan2
- AKR1B10 | c.280G>C p.E94Q | Missense Mutation (SNP) | VAF 44/208 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100610268; called by muse, mutect2, varscan2
- ALOX12B | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as COSV59871509; called by muse, varscan2
- ANKRD17 | c.3348T>C p.G1116= | Splice Region (SNP) | VAF 32/121 reads (26%) | catalogued as rs1436548225, COSV100430081; called by muse, mutect2, varscan2
- APLNR | c.449C>T p.T150M | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.787); catalogued as rs751033294, COSV99951699; called by muse, mutect2, varscan2
- ARHGAP9 | c.423G>C p.R141S | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV100712545; called by muse, mutect2, varscan2
- ARNT | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62230272; called by muse, mutect2, varscan2
- ATN1 | c.1127C>T p.S376L | Missense Mutation (SNP) | VAF 48/189 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.067); catalogued as COSV100755985; called by muse, mutect2, varscan2
- CASP6 | c.541C>T p.Q181* | Nonsense Mutation (SNP) | VAF 25/117 reads (21%) | catalogued as COSV99488898; called by muse, mutect2, varscan2
- CBX3 | c.425+1G>C p.X142_splice | Splice Site (SNP) | VAF 21/90 reads (23%) | catalogued as COSV100522979, COSV100523031; called by muse, mutect2
- CCAR1 | c.2032G>C p.E678Q | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); catalogued as COSV99771486; called by muse, mutect2, varscan2
- CD80 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs777455046, COSV51802498; called by muse, mutect2, varscan2
- CDK17 | c.817G>C p.D273H | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99703154; called by muse, mutect2, varscan2
- CGB8 | c.437C>G p.P146R | Missense Mutation (SNP) | VAF 24/237 reads (10%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.001); catalogued as rs746017552; called by muse, mutect2, varscan2
- CHD4 | c.4333G>A p.A1445T (on ENST00000357008 / NM_001363606.2; = p.A1458T on NM_001273.5) | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100539428; called by muse, mutect2, varscan2
- CLMN | c.1457C>T p.S486F | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.564); catalogued as COSV100113009; called by muse, mutect2, varscan2
- COX11 | c.590G>C p.G197A | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100174130; called by muse, mutect2, varscan2
- DAB2 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100298431; called by muse, mutect2, varscan2
- DEUP1 | c.1550G>A p.R517K | Missense Mutation (SNP) | VAF 95/221 reads (43%) | SIFT tolerated (0.83); PolyPhen benign (0.009); catalogued as COSV99977720; called by muse, mutect2, varscan2
- DRP2 | c.2276C>G p.S759C | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.99); catalogued as COSV100872084, COSV65809972; called by muse, mutect2, varscan2
- EFCAB13 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 57/250 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV100517013; called by muse, mutect2, varscan2
- EPB41L1 | c.2335G>A p.E779K | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.743); catalogued as COSV99152964; called by muse, varscan2
- EQTN | c.558C>G p.I186M | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV101192554; called by muse, mutect2, varscan2
- ESPL1 | c.3974C>T p.S1325F | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as COSV99229875; called by muse, mutect2, varscan2
- GABBR1 | c.962C>T p.S321L | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV63545106; called by muse, mutect2, varscan2
- GAREM1 | c.1031G>T p.R344L | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99330315, COSV99331506; called by muse, mutect2, varscan2
- GLYR1 | c.1102G>A p.V368I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.92); PolyPhen benign (0.01); catalogued as rs200059061, COSV100424603; called by muse, mutect2
- GOLGA1 | c.651G>A p.M217I | Missense Mutation (SNP) | VAF 56/272 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV101002621; called by muse, mutect2, varscan2
- GSN | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs761433282, COSV100376260; called by muse, mutect2, varscan2
- H2BC12 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.124); catalogued as COSV100804681, COSV63616685; called by muse, mutect2, varscan2
- HAS2 | c.419G>A p.R140K | Missense Mutation (SNP) | VAF 92/542 reads (17%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV100392237; called by muse, mutect2, varscan2
- HOMEZ | c.704G>A p.R235K | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100664087, COSV100664213; called by muse, varscan2
- HSPA4 | c.119C>G p.S40C | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV100507915; called by muse, mutect2, varscan2
- KCNJ2 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54663471, COSV99696346; called by muse, mutect2, varscan2
- KIF18A | c.1202C>G p.T401S | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV99589202; called by muse, mutect2, varscan2
- KMT2D | c.7228C>T p.R2410* | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | catalogued as CM114905, COSV56416426; called by muse, mutect2
- LAMTOR3 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99896220; called by muse, mutect2, varscan2
- LSM8 | c.130C>T p.R44* | Nonsense Mutation (SNP) | VAF 44/189 reads (23%) | catalogued as rs767758783, COSV50800553; called by muse, mutect2, varscan2
- MED14 | c.3484C>T p.R1162C | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1165393504, COSV61357585, COSV61357804; called by muse, mutect2, varscan2
- MEF2C | c.1352G>A p.R451K | Missense Mutation (SNP) | VAF 71/346 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as COSV100426330; called by muse, mutect2, varscan2
- MGAM | c.4562G>C p.G1521A | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV101527784; called by muse, mutect2, varscan2
- MPP6 | c.1513G>A p.D505N | Missense Mutation (SNP) | VAF 48/243 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56040657; called by muse, mutect2, varscan2
- MRPL9 | c.732G>T p.K244N | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); catalogued as rs200843412, COSV100162742; called by muse, mutect2, varscan2
- MUC16 | c.30734C>T p.S10245F | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV67450091; called by muse, mutect2, varscan2
- MUC5B | c.8722G>A p.V2908I | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.95); PolyPhen benign (0.035); catalogued as rs745678847, COSV71597420; called by muse, mutect2, varscan2
- MYBPC1 | c.1496G>C p.G499A (on ENST00000550270 / NM_206820.2; = p.G524A on NM_002465.4) | Missense Mutation (SNP) | VAF 61/294 reads (21%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.524); catalogued as COSV100638316; called by muse, mutect2, varscan2
- MYO5B | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV99546496; called by muse, mutect2, varscan2
- NIPBL | c.2459A>G p.N820S | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99243065; called by muse, mutect2
- NRDC | c.1654C>G p.L552V | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.309); catalogued as COSV100703964, COSV61409086; called by muse, mutect2, varscan2
- NSD2 | c.3429C>A p.S1143R | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100374008; called by muse, mutect2, varscan2
- NSRP1 | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV99898641; called by muse, mutect2
- NUP188 | c.1750G>C p.D584H | Missense Mutation (SNP) | VAF 55/257 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101001522; called by muse, mutect2, varscan2
- OR52J3 | c.268G>C p.D90H | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV100984957; called by muse, mutect2, varscan2
- PACS2 | c.1824C>G p.F608L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as COSV100331048; called by muse, mutect2, varscan2
- PAPSS1 | c.1707G>C p.K569N | Missense Mutation (SNP) | VAF 48/240 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.594); catalogued as COSV54489158, COSV99492495; called by muse, varscan2
- PBXIP1 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.602); catalogued as COSV100869920; called by muse, mutect2, varscan2
- PCDH9 | c.1690G>T p.D564Y | Missense Mutation (SNP) | VAF 36/208 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100124149; called by muse, mutect2, varscan2
- PCDHA1 | c.11C>A p.S4Y | Missense Mutation (SNP) | VAF 54/308 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.023); catalogued as COSV100974555, COSV65373629; called by muse, mutect2, varscan2
- PDE4D | c.1357G>A p.D453N (on ENST00000340635 / NM_001104631.2; = p.D317N on NM_006203.4) | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.977); catalogued as COSV100402260; called by muse, mutect2, varscan2
- PI4KA | c.2720C>T p.S907L | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as COSV99749039; called by muse, mutect2, varscan2
- POLL | c.734C>G p.S245* | Nonsense Mutation (SNP) | VAF 26/100 reads (26%) | catalogued as COSV100150498; called by muse, varscan2
- POLRMT | c.3384C>A p.D1128E | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99242387; called by muse, mutect2, varscan2
- PRDM9 | c.1198C>G p.Q400E | Missense Mutation (SNP) | VAF 35/252 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.428); catalogued as COSV57013131, COSV99691429; called by muse, mutect2, varscan2
- PTPRT | c.1843C>T p.Q615* | Nonsense Mutation (SNP) | VAF 32/188 reads (17%) | catalogued as COSV62021346; called by muse, mutect2, varscan2
- PYGM | c.1748A>T p.H583L | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99377703; called by muse, mutect2, varscan2
- RAP2B | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.146); catalogued as COSV100059179; called by muse, mutect2, varscan2
- RASL12 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV99585236; called by muse, mutect2, varscan2
- RBM26 | c.1487C>T p.S496F | Missense Mutation (SNP) | VAF 79/304 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as COSV99936709; called by muse, mutect2, varscan2
- RFTN2 | c.634G>C p.E212Q | Missense Mutation (SNP) | VAF 69/234 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.898); catalogued as COSV54387322, COSV54390263; called by muse, mutect2, varscan2
- RHOBTB1 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.755); catalogued as COSV61958540; called by muse, mutect2, varscan2
- RPGRIP1L | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 74/322 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs565245381, COSV50914557; called by muse, mutect2, varscan2
- RPTOR | c.482A>G p.N161S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV100157509; called by muse, mutect2, varscan2
- SEPHS2 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.03); catalogued as COSV101529338; called by muse, mutect2, varscan2
- SEPHS2 | c.179G>A p.Sec60* | Nonsense Mutation (SNP) | VAF 6/12 reads (50%) | catalogued as COSV101529349; called by muse, mutect2
- SETD1A | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.275); catalogued as COSV99353839; called by muse, mutect2, varscan2
- SFRP4 | c.311C>A p.A104E | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52258573, COSV99554731; called by muse, mutect2, varscan2
- SFSWAP | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV55521853; called by muse, mutect2, varscan2
- SH3GL2 | c.694A>T p.I232F | Missense Mutation (SNP) | VAF 39/190 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV101014884; called by muse, mutect2, varscan2
- SLC35G6 | c.895T>A p.Y299N | Missense Mutation (SNP) | VAF 58/235 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100263837; called by muse, mutect2, varscan2
- SLC6A13 | c.1222C>T p.H408Y | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.115); catalogued as COSV100569824, COSV100570100; called by muse, mutect2, varscan2
- SLC7A1 | c.1090G>C p.A364P | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101060316; called by muse, mutect2, varscan2
- SLC7A14 | c.2199G>C p.Q733H | Missense Mutation (SNP) | VAF 51/273 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV99201109; called by muse, mutect2, varscan2
- SLC8A2 | c.2329G>A p.V777I | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.112); catalogued as rs867459624, COSV52639978; called by muse, mutect2, varscan2
- SNX25 | c.370C>T p.L124F | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV53014788, COSV99253603; called by muse, mutect2, varscan2
- STAB2 | c.2266G>C p.D756H | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV66345623, COSV66346019; called by muse, mutect2, varscan2
- STAU1 | c.1433C>T p.S478L (on ENST00000371856 / NM_001319135.1; = p.S397L on NM_004602.3) | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100574632; called by muse, mutect2, varscan2
- SYNE3 | c.2076G>T p.R692S | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.661); catalogued as rs1354127661, COSV100516623; called by muse, mutect2, varscan2
- TAFA2 | c.11G>C p.R4T | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.143); catalogued as COSV101354051, COSV69183245; called by muse, mutect2, varscan2
- TCF7 | c.463dup p.H155Pfs*37 | Frame Shift Ins (INS) | VAF 12/110 reads (11%) | catalogued as rs771602751; called by mutect2, varscan2
- TGDS | c.506C>G p.S169C | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99725340; called by muse, mutect2, varscan2
- TM9SF3 | c.836G>C p.G279A | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64456665; called by muse, mutect2, varscan2
- TMC7 | c.1860C>G p.I620M | Missense Mutation (SNP) | VAF 76/422 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.19); catalogued as COSV100432867; called by muse, mutect2, varscan2
- TTLL2 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 89/362 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as rs571140155, COSV99515009; called by muse, mutect2, varscan2
- UBR4 | c.5406G>A p.Q1802= | Splice Region (SNP) | VAF 15/53 reads (28%) | catalogued as COSV100922060; called by muse, mutect2, varscan2
- USH2A | c.4208C>T p.S1403F | Missense Mutation (SNP) | VAF 45/194 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100243632; called by muse, mutect2, varscan2
- USP34 | c.8009G>A p.R2670Q | Missense Mutation (SNP) | VAF 116/541 reads (21%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.921); catalogued as rs891957560, COSV68408958; called by muse, mutect2, varscan2
- VN1R1 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.618); catalogued as rs1026436506, COSV100320782, COSV58090863; called by muse, mutect2, varscan2
- WHAMM | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.062); catalogued as rs199867688, COSV99725304; called by muse, mutect2, varscan2
- ZBED6CL | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100550655; called by muse, mutect2, varscan2
- ZIM3 | c.875C>G p.S292* | Nonsense Mutation (SNP) | VAF 125/331 reads (38%) | catalogued as COSV99518798; called by muse, mutect2, varscan2
- ZNF160 | c.85C>G p.Q29E | Missense Mutation (SNP) | VAF 72/218 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100762504; called by muse, mutect2, varscan2
- BIRC6 | c.2777_2796del p.V926Gfs*3 | Frame Shift Del (DEL) | VAF 27/183 reads (15%) | called by mutect2, pindel
- HLA-A | c.61C>T p.Q21* | Nonsense Mutation (SNP) | VAF 15/66 reads (23%) | called by muse, mutect2
- IGHV1OR21-1 | c.326A>G p.D109G | Missense Mutation (SNP) | VAF 79/770 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMEM132A | c.1367_1396del p.A456_K465del (on ENST00000453848 / NM_178031.3; = p.A457_K466del on NM_017870.4) | In Frame Del (DEL) | VAF 8/46 reads (17%) | called by mutect2, pindel
- USH2A | c.12381_12382del p.Y4128Hfs*24 | Frame Shift Del (DEL) | VAF 13/57 reads (23%) | called by pindel, varscan2
- ZNF319 | c.188del p.P63Hfs*96 | Frame Shift Del (DEL) | VAF 17/69 reads (25%) | called by mutect2, pindel, varscan2
- ALOX12B | c.828G>C p.L276= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs1466503688, COSV100047841; called by muse, varscan2
- AMOTL2 | c.897C>T p.A299= | Silent (SNP) | VAF 28/117 reads (24%) | catalogued as COSV99998355; called by muse, mutect2, varscan2
- ATP8B2 | c.1101C>A p.L367= (on ENST00000672630; = p.L334= on NM_001005855.2) | Silent (SNP) | VAF 130/584 reads (22%) | catalogued as COSV100528293; called by muse, mutect2, varscan2
- BRINP1 | c.1425C>T p.I475= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV99777146; called by muse, mutect2, varscan2
- CAMK1D | c.870C>T p.H290= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs764307882, COSV101124009; called by muse, mutect2, varscan2
- CCDC114 | c.1263C>A p.L421= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV59557038; called by muse, mutect2, varscan2
- CCDC151 | c.90G>A p.R30= | Silent (SNP) | VAF 28/131 reads (21%) | catalogued as COSV99372026; called by muse, mutect2, varscan2
- CHML | c.312C>T p.Y104= | Silent (SNP) | VAF 123/484 reads (25%) | catalogued as rs113330678; called by muse, mutect2, varscan2
- CKAP4 | c.1467G>A p.L489= | Silent (SNP) | VAF 35/132 reads (27%) | catalogued as COSV100952537; called by muse, mutect2, varscan2
- CNOT1 | c.1959C>G p.A653= | Silent (SNP) | VAF 34/151 reads (23%) | catalogued as COSV100410215; called by muse, mutect2, varscan2
- CPM | c.1149G>A p.Q383= | Silent (SNP) | VAF 32/161 reads (20%) | catalogued as COSV100615022, COSV100615308; called by muse, mutect2, varscan2
- CSMD3 | c.3757C>T p.L1253= (on ENST00000297405 / NM_001363185.1; = p.L1149= on NM_052900.3) | Silent (SNP) | VAF 36/288 reads (13%) | catalogued as COSV99850203; called by muse, mutect2, varscan2
- DNAH9 | c.9492C>G p.L3164= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV99308607; called by muse, mutect2
- DPP6 | c.2253G>A p.A751= (on ENST00000377770 / NM_001364500.2; = p.A689= on NM_001936.5) | Silent (SNP) | VAF 75/340 reads (22%) | catalogued as rs748957885, COSV59599208; called by muse, mutect2, varscan2
- EDRF1 | c.747C>T p.F249= | Silent (SNP) | VAF 20/111 reads (18%) | catalogued as rs150180630; called by muse, mutect2, varscan2
- EFCC1 | c.1488G>A p.L496= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV101460038, COSV71401865; called by muse, mutect2, varscan2
- EXOC7 | c.1080G>A p.E360= (on ENST00000335146 / NM_001145297.4; = p.E278= on NM_015219.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV100135867; called by muse, mutect2, varscan2
- FAM98A | c.417T>C p.G139= | Silent (SNP) | VAF 42/230 reads (18%) | catalogued as COSV99479594; called by muse, mutect2, varscan2
- FARP2 | c.36G>A p.Q12= | Silent (SNP) | VAF 43/130 reads (33%) | catalogued as COSV99885702; called by muse, mutect2, varscan2
- FCSK | c.3254G>A p.*1085= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV99851344; called by muse, mutect2, varscan2
- FER1L6 | c.174C>T p.V58= | Silent (SNP) | VAF 119/257 reads (46%) | catalogued as COSV101206233, COSV67550159; called by muse, mutect2, varscan2
- FYB2 | c.903C>T p.P301= | Silent (SNP) | VAF 46/224 reads (21%) | catalogued as COSV100599847; called by muse, mutect2, varscan2
- GABRG2 | c.402C>T p.V134= | Silent (SNP) | VAF 32/177 reads (18%) | catalogued as COSV100729892; called by muse, mutect2, varscan2
- GCFC2 | c.870G>A p.L290= | Silent (SNP) | VAF 54/249 reads (22%) | catalogued as rs766586628, COSV100319757; called by muse, mutect2, varscan2
- GDPD2 | c.948C>T p.F316= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV100978703, COSV100978725; called by muse, mutect2, varscan2
- GRK7 | c.135C>T p.C45= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV53822209; called by muse, mutect2, varscan2
- HSF1 | c.375G>A p.L125= | Silent (SNP) | VAF 20/153 reads (13%) | catalogued as rs782221015, COSV101275173; called by muse, mutect2, varscan2
- IGHV1-46 | c.210C>T p.I70= | Silent (SNP) | VAF 55/244 reads (23%) | called by muse, mutect2, varscan2
- KRTAP20-2 | c.197G>A p.*66= | Silent (SNP) | VAF 52/175 reads (30%) | catalogued as rs752395885, COSV100424546; called by muse, mutect2, varscan2
- LGALS12 | c.837G>A p.A279= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as rs752434826, COSV99737408; called by muse, mutect2, varscan2
- MTMR11 | c.975C>T p.L325= (on ENST00000439741 / NM_001145862.2; = p.L253= on NM_181873.3) | Silent (SNP) | VAF 66/286 reads (23%) | catalogued as COSV100809355; called by muse, mutect2
- OR2W3 | c.189C>T p.L63= | Silent (SNP) | VAF 52/339 reads (15%) | catalogued as rs201464457, COSV64455989; called by muse, mutect2, varscan2
- OSER1 | c.792G>A p.V264= | Silent (SNP) | VAF 32/199 reads (16%) | catalogued as COSV99667460; called by muse, varscan2
- PLEKHM2 | c.495C>T p.Y165= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as COSV101009221; called by muse, mutect2, varscan2
- POLL | c.858C>T p.L286= | Silent (SNP) | VAF 46/168 reads (27%) | catalogued as COSV100150496; called by muse, varscan2
- PPP2R1A | c.255C>T p.Y85= | Silent (SNP) | VAF 27/155 reads (17%) | catalogued as rs760874499, COSV100436535, COSV59042597; called by muse, mutect2, varscan2
- PRAMEF8 | c.1002C>T p.F334= | Silent (SNP) | VAF 45/218 reads (21%) | called by muse, mutect2, varscan2
- PRDM16 | c.3060G>A p.Q1020= | Silent (SNP) | VAF 28/146 reads (19%) | catalogued as COSV54578243, COSV99579264; called by muse, mutect2, varscan2
- SDK1 | c.3996G>A p.G1332= | Silent (SNP) | VAF 30/125 reads (24%) | catalogued as COSV101269960; called by muse, mutect2, varscan2
- SEMA6A | c.1950C>T p.L650= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99146040; called by muse, mutect2, varscan2
- SERPINB6 | c.1110C>T p.A370= (on ENST00000612421 / NM_001271823.2; = p.A351= on NM_004568.6) | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as rs748178838, COSV100177627; called by muse, mutect2, varscan2
- SH3RF2 | c.510C>T p.I170= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as rs137960488; called by muse, mutect2, varscan2
- SIRPG | c.231C>T p.I77= | Silent (SNP) | VAF 47/206 reads (23%) | catalogued as COSV99404040; called by muse, mutect2
- TBC1D19 | c.990G>A p.L330= | Silent (SNP) | VAF 43/165 reads (26%) | catalogued as COSV99336878; called by muse, mutect2, varscan2
- TBX18 | c.582G>C p.V194= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as COSV100858603; called by muse, varscan2
- TFG | c.774G>A p.P258= | Silent (SNP) | VAF 31/216 reads (14%) | catalogued as rs1367793822, COSV52546281; ClinVar: likely benign; called by muse, mutect2
- TIMMDC1 | c.618G>A p.L206= | Silent (SNP) | VAF 31/180 reads (17%) | catalogued as COSV51786041; called by muse, mutect2, varscan2
- TRAV21 | c.75G>A p.Q25= | Silent (SNP) | VAF 34/194 reads (18%) | called by muse, mutect2, varscan2
- WDR90 | c.4771C>T p.L1591= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as rs762939992, COSV53471319, COSV99554293; called by muse, mutect2, varscan2
- WLS | c.267C>T p.D89= | Silent (SNP) | VAF 20/113 reads (18%) | catalogued as COSV99260689; called by muse, mutect2, varscan2
- XDH | c.339C>T p.C113= | Silent (SNP) | VAF 63/261 reads (24%) | catalogued as rs118042822, COSV65147544; called by muse, mutect2, varscan2
- ZNF592 | c.2697C>G p.L899= | Silent (SNP) | VAF 31/93 reads (33%) | catalogued as rs1567077478, COSV100246167; called by muse, mutect2, varscan2
- DCHS2 | n.1034G>A | RNA (SNP) | VAF 27/119 reads (23%) | catalogued as COSV100253428; called by muse, mutect2, varscan2
- DST | c.4297-3681G>A | Intron (SNP) | VAF 27/97 reads (28%) | catalogued as COSV99760663; called by muse, mutect2, varscan2
- SLC22A17 | n.1430C>T | RNA (SNP) | VAF 25/95 reads (26%) | catalogued as rs1245455912, COSV99249104; called by muse, mutect2, varscan2
